Somatic mutation profile of tumor specimen TCGA-CJ-4869-01A (aliquot TCGA-CJ-4869-01A-02D-1429-08) from TCGA case TCGA-CJ-4869, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 49.1 years (17,923 days).
Specimen TCGA-CJ-4869-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a2166b4-60dc-4d46-bed7-83f6bd94113d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4869-11A (Solid Tissue Normal), aliquot TCGA-CJ-4869-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edac8204-4418-46b7-ae7f-bf0da4cd11a2

The open-access MAF lists 75 somatic variants for this specimen: 63 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 9, Frame Shift Del 4, Intron 3, Frame Shift Ins 2, In Frame Del 2, Splice Site 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.1045del p.Q349Kfs*10 | Frame Shift Del (DEL) | VAF 21/120 reads (18%) | catalogued as COSV56857390; called by mutect2, pindel, varscan2
- ADA2 | c.1267A>T p.N423Y (on ENST00000262607; = p.N182Y on NM_177405.3) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52832820; called by muse, varscan2
- ADGRA2 | c.3188T>A p.L1063H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55104931; called by muse, mutect2, varscan2
- ANK3 | c.2879T>C p.L960P (on ENST00000280772 / NM_001320874.2; = p.L94P on NM_001149.3) | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV55073120; called by muse, mutect2, varscan2
- ANKRD11 | c.4726G>A p.G1576S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV56365649, COSV56367889; called by muse, mutect2, varscan2
- BCL9L | c.4414C>T p.H1472Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.546); catalogued as COSV52687758; called by muse, mutect2, varscan2
- C11orf16 | c.515C>A p.P172H | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58168599; called by muse, mutect2, varscan2
- CCDC151 | c.680C>G p.T227S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); catalogued as COSV62698751; called by muse, mutect2, varscan2
- CCPG1 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 122/690 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373056381; called by muse, mutect2, varscan2
- CLASP1 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV55333917; called by muse, mutect2, varscan2
- COL14A1 | c.1661C>A p.T554N | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.081); catalogued as rs749880566, COSV52863276; called by muse, mutect2, varscan2
- DIP2B | c.1878A>C p.R626S | Missense Mutation (SNP) | VAF 66/292 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV56589112; called by muse, mutect2, varscan2
- DPEP3 | c.1407C>A p.Y469* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV52052326, COSV52052783; called by muse, mutect2, varscan2
- EP400 | c.8959A>G p.T2987A | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.574); catalogued as COSV57781357; called by muse, mutect2, varscan2
- FAT4 | c.4742G>T p.S1581I | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67895275; called by muse, mutect2, varscan2
- FZD10 | c.998C>T p.T333I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772031428, COSV99969533; called by muse, mutect2, varscan2
- GPR142 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs1388676009, COSV59520064; called by muse, mutect2, varscan2
- GPR89A | c.739A>C p.I247L | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58260042; called by muse, mutect2, varscan2
- HERPUD2 | c.548A>C p.Y183S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV60946508; called by muse, mutect2, varscan2
- HSPA4 | c.2252T>C p.L751P | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.603); catalogued as COSV59183196; called by muse, mutect2, varscan2
- HYDIN | c.6175T>A p.Y2059N | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.277); catalogued as COSV99993358; called by muse, mutect2, varscan2
- IARS2 | c.1479G>T p.K493N | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.701); catalogued as COSV56962554; called by muse, mutect2
- JAGN1 | c.326T>A p.L109H | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57062693; called by muse, mutect2, varscan2
- KLHDC10 | c.1060G>C p.V354L | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV59053326; called by muse, mutect2, varscan2
- KRT27 | c.345G>T p.K115N | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56972826; called by muse, mutect2, varscan2
- LRBA | c.5708T>A p.L1903Q | Missense Mutation (SNP) | VAF 61/392 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63960865; called by muse, mutect2, varscan2
- MAPK7 | c.805C>A p.H269N | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as COSV55191291; called by muse, mutect2, varscan2
- MARCHF11 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.057); catalogued as COSV60132652; called by muse, mutect2, varscan2
- METAP2 | c.591-2A>T p.X197_splice | Splice Site (SNP) | VAF 25/98 reads (26%) | catalogued as rs781369643, COSV54150299; called by muse, mutect2, varscan2
- MICU2 | c.1271A>T p.E424V | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV66675044; called by muse, mutect2, varscan2
- MUC16 | c.25994C>T p.A8665V | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.047); catalogued as COSV67481912; called by muse, mutect2, varscan2
- MYO16 | c.4062C>A p.S1354R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV62757860; called by muse, mutect2, varscan2
- NTRK1 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV62327637; called by muse, mutect2
- OCA2 | c.1349C>A p.T450K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM085601, CM100992, COSV62337789, COSV62353533; called by muse, mutect2, varscan2
- PGR | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV54799223, COSV54801600; called by muse, mutect2, varscan2
- PROX1 | c.514A>T p.I172L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54781994; called by muse, varscan2
- R3HDML | c.749T>G p.F250C | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV53837196; called by muse, mutect2, varscan2
- REV3L | c.900A>T p.K300N | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs866295990, COSV62621848; called by muse, mutect2, varscan2
- RFXAP | c.768T>G p.N256K | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.234); catalogued as COSV55226192; called by muse, mutect2, varscan2
- ROS1 | c.2340C>A p.D780E | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.547); catalogued as COSV63859467; called by muse, mutect2, varscan2
- RRAGC | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 45/314 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV65931781; called by muse, mutect2, varscan2
- SAMD9 | c.2521C>A p.P841T | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV66076935; called by muse, mutect2, varscan2
- SLC10A5 | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.651); catalogued as COSV72828401, COSV72828446; called by muse, mutect2, varscan2
- SLC6A19 | c.836_838del p.F279del | In Frame Del (DEL) | VAF 22/161 reads (14%) | catalogued as rs1188882343; called by mutect2, pindel, varscan2
- SP140 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763966598, COSV59451528; called by muse, mutect2, varscan2
- SULF1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV52688851; called by muse, mutect2, varscan2
- TBC1D2 | c.232C>A p.L78M | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59787410; called by muse, mutect2, varscan2
- TBX21 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs745479696, COSV51595588; called by muse, mutect2, varscan2
- TDRD1 | c.1832-2A>T p.X611_splice | Splice Site (SNP) | VAF 15/111 reads (14%) | catalogued as COSV52593851; called by muse, mutect2, varscan2
- TEX11 | c.1453C>T p.R485* (on ENST00000344304; = p.R470* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV60235840; called by muse, mutect2, varscan2
- TNC | c.370A>T p.S124C | Missense Mutation (SNP) | VAF 88/475 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60788507; called by muse, mutect2, varscan2
- TTN | c.52482A>T p.Q17494H (on ENST00000591111; = p.Q10070H on NM_003319.4) | Missense Mutation (SNP) | VAF 16/100 reads (16%) | PolyPhen benign (0.247); catalogued as COSV60239394; called by muse, mutect2, varscan2
- UROD | c.688A>G p.N230D | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV55801560; called by muse, mutect2, varscan2
- VIM | c.1138C>T p.L380F | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56407096; called by muse, mutect2, varscan2
- VPS4B | c.1081C>A p.H361N | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53070398; called by muse, mutect2, varscan2
- WDR47 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 9/257 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV63056852, COSV63059098; called by muse, mutect2
- BAP1 | c.1046del p.N349Tfs*13 | Frame Shift Del (DEL) | VAF 32/152 reads (21%) | called by mutect2, pindel, varscan2
- CACNA1C | c.2815del p.V939Ffs*12 | Frame Shift Del (DEL) | VAF 28/230 reads (12%) | called by mutect2, pindel, varscan2
- CXXC4 | c.520_521dup p.N174Kfs*42 | Frame Shift Ins (INS) | VAF 23/106 reads (22%) | called by mutect2, pindel, varscan2
- KLHL24 | c.1080_1082del p.L361del | In Frame Del (DEL) | VAF 23/121 reads (19%) | called by mutect2, pindel, varscan2
- MUC2 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SPATA45 | c.39dup p.H14Tfs*17 | Frame Shift Ins (INS) | VAF 40/257 reads (16%) | called by mutect2, pindel, varscan2
- ZBTB11 | c.1827_1828del p.A610Lfs*25 | Frame Shift Del (DEL) | VAF 18/144 reads (13%) | called by mutect2, pindel, varscan2
- BDP1 | c.2130G>A p.K710= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV62430615, COSV62433288; called by muse, mutect2, varscan2
- BRD9 | c.1722G>A p.E574= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as rs764239470, COSV60248890; called by muse, mutect2, varscan2
- DOK4 | c.462G>A p.E154= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs1408964659, COSV54673855; called by muse, mutect2, varscan2
- FAM120AOS | c.600T>C p.A200= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV52908641; called by muse, mutect2, varscan2
- PLAC1 | c.114A>T p.T38= | Silent (SNP) | VAF 83/200 reads (42%) | catalogued as COSV63656767; called by muse, mutect2, varscan2
- RPAP3 | c.1464A>C p.T488= | Silent (SNP) | VAF 38/234 reads (16%) | catalogued as COSV50042533; called by muse, mutect2, varscan2
- TENM1 | c.225A>G p.E75= | Silent (SNP) | VAF 52/147 reads (35%) | catalogued as COSV64439026; called by muse, mutect2, varscan2
- UNC79 | c.1206G>T p.R402= (on ENST00000393151 / NM_001346218.2; = p.R225= on NM_020818.5) | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV56402374; called by muse, mutect2, varscan2
- VWC2 | c.816C>A p.I272= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV61489373; called by muse, mutect2, varscan2
- PCDHGB2 | c.2421+10A>T | Intron (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2
- RGS3 | c.3081-266C>T | Intron (SNP) | VAF 33/169 reads (20%) | catalogued as COSV100636897; called by muse, mutect2, varscan2
- SLIT2 | c.1463-621_1463-610del | Intron (DEL) | VAF 17/127 reads (13%) | called by mutect2, pindel
